Gene-level copy-number profile of tumor specimen TCGA-P5-A5F4-01A from TCGA case TCGA-P5-A5F4, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 35.2 years (12,851 days).
Specimen TCGA-P5-A5F4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.b1f09ffb-2b37-46dc-8391-f21447415b3f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P5-A5F4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7c25f825-1ba4-4947-b05b-a396b67a1727

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 662; copy number 1: 10,485; copy number 2: 47,681; copy number 3: 982.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P5-A5F4-01A-11D-A288-01): tumor purity 0.6, ploidy 3.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 662 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:38,078,529–50,748,657, 298 genes (within-gene range 0–1) (broad region; genes not listed).
- chr12:53,241,889–56,787,790, 213 genes (broad region; genes not listed).
- chr12:109,713,825–115,886,137, 149 genes (broad region; genes not listed).
- chr12:115,961,187–116,082,676, 2 genes: AC012157.2, RNU6-1188P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,485. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
